Gene-level copy-number profile of tumor specimen ALCH-B4BL-TTP1-A from ALCHEMIST case ALCH-B4BL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.1 years (27,070 days).
Specimen ALCH-B4BL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ced8009e-e3e2-4554-a71c-d914de0bff33.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4BL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/45614e2c-1d25-4c78-8dc4-d249b3014c98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 244; copy number 1: 21,495; copy number 2: 34,279; copy number 3: 2,168; copy number 4: 155; copy number 5: 16; copy number 6: 3; copy number 9: 1; copy number 10: 3; copy number 12: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 220 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–1,074,306, 19 genes: AL645608.6, AL645608.2, AL645608.4, LINC02593, SAMD11, NOC2L, KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223.
- chr1:6,412,418–6,466,175, 5 genes (within-gene range 0–1): HES2, ESPN, MIR4252, AL031848.1, TNFRSF25.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr1:27,176,751–27,201,473, 2 genes: AL590640.2, CHCHD3P3.
- chr4:7,939,001–9,710,812, 75 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:11,421,476–11,475,908, 1 gene (within-gene range 0–1): FAM167A.
- chr8:12,378,679–12,400,366, 2 genes (within-gene range 0–1): AC087203.2, DEFB109A.
- chr9:21,966,929–22,214,672, 9 genes (within-gene range 0–1): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:129,665,647–129,722,674, 2 genes: PRRX2, PRRX2-AS1.
- chr9:135,693,407–135,795,508, 2 genes: SOHLH1, KCNT1.
- chr11:440,399–440,693, 1 gene (within-gene range 0–1): RN7SL838P.
- chr11:494,512–537,287, 3 genes: RNH1, AC137894.1, HRAS.
- chr11:560,404–568,457, 3 genes (within-gene range 0–1): RASSF7, MIR210HG, MIR210.
- chr13:22,696,023–23,170,597, 13 genes: FTH1P7, DDX39AP1, SNORD36, RPL7AP73, IPMKP1, RFESDP1, LINC00621, BASP1P1, NUS1P2, AL157931.1, HMGA1P6, RNY3P4, LINC00362.
- chr13:26,557,683–26,760,786, 5 genes: WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12.
- chr15:25,176,832–25,250,940, 41 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:61,239,906–61,240,331, 1 gene: AC107905.1.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr17:2,748,078–2,748,182, 2 genes (within-gene range 0–1): MIR1253, hsa-mir-1253.
- chr17:18,450,244–18,475,920, 4 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–1): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–1): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr18:34,493,290–34,903,504, 4 genes: DTNA, AC013290.1, AC022601.1, AC068506.1.
- chr19:13,874,699–13,906,452, 3 genes (within-gene range 0–1): MIR181C, MIR181D, C19orf57.
- chr22:20,126,402–20,151,055, 3 genes (within-gene range 0–1): SNORA77B, ZDHHC8, CCDC188.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,813,225–149,900,798, 14 genes, copy number 5: H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1.
- chr17:18,390,153–18,400,961, 2 genes, copy number 5: AL353997.5, TBC1D3P4.
- chr17:18,476,737–18,494,945, 1 gene, copy number 9: LGALS9C.
- chr21:8,680,538–8,680,934, 1 gene, copy number 13: CR381572.2.
- chr21:10,612,455–10,649,835, 3 genes, copy number 6: SLC25A15P4, AF254982.1, IGHV1OR21-1.
- chr21:44,172,169–44,194,338, 2 genes, copy number 12: AP001056.2, AP001056.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 10: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 19,179. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
